Somatic mutation profile of tumor specimen 0DDKCR from CCDI case PBBPAA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.5 years (3,828 days).
Specimen 0DDKCR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c1d4f58e-57c3-4470-85bb-f823fdd3ffbe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DDKDB (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c818fd95-de28-44cd-8401-4fd3522a9ca4

The open-access MAF lists 5 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Silent 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GCSAM | c.301A>T p.N101Y | Missense Mutation (SNP) | VAF 27/879 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.742); catalogued as COSV100453205; called by muse, mutect2
- TUT7 | c.2923A>G p.K975E | Missense Mutation (SNP) | VAF 17/576 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2
- MRPL32 | c.180T>C p.N60= | Silent (SNP) | VAF 103/517 reads (20%) | called by muse, mutect2, varscan2
- TNIP1 | c.978C>G p.S326= | Silent (SNP) | VAF 18/604 reads (3%) | called by muse, mutect2
- GDI1 | c.-77C>T | 5'UTR (SNP) | VAF 34/108 reads (31%) | catalogued as rs781846205; called by mutect2, varscan2
